Somatic mutation profile of tumor specimen 0DWESB from CCDI case PBCPCS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 1.6 years (587 days).
Specimen 0DWESB: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5897a75b-a1d8-4092-9564-8592100fe9ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWES2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/046aad25-b27c-4194-a5a9-8266500d5132

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 96/217 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- CTNNA3 | c.2329C>A p.H777N | Missense Mutation (SNP) | VAF 162/367 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV101041713, COSV65527830; called by muse, mutect2, varscan2
- ENPP2 | c.2540C>A p.P847Q (on ENST00000075322 / NM_001040092.3; = p.P899Q on NM_006209.5) | Missense Mutation (SNP) | VAF 164/402 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99309598; called by muse, mutect2
- ERN1 | c.2801C>T p.T934I | Missense Mutation (SNP) | VAF 27/324 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV101458370; called by muse, mutect2
- IL17RC | c.983C>T p.P328L (on ENST00000295981 / NM_153461.4; = p.P242L on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/243 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs764646516, COSV55973641; called by muse, mutect2, varscan2
- IMPG1 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 115/271 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs763194922; called by muse, mutect2, varscan2
- RPA1 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 108/266 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1411457047; called by muse, mutect2, varscan2
- COL2A1 | c.3657C>A p.D1219E | Missense Mutation (SNP) | VAF 205/462 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CRB3 | c.281G>C p.R94P | Missense Mutation (SNP) | VAF 101/227 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAT2 | c.7654G>T p.V2552F | Missense Mutation (SNP) | VAF 118/364 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- FZD2 | c.92T>C p.I31T | Missense Mutation (SNP) | VAF 135/322 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- MAP6 | c.290C>A p.A97E | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- OSBPL1A | c.2035T>G p.F679V (on ENST00000319481 / NM_080597.4; = p.F166V on NM_018030.4) | Missense Mutation (SNP) | VAF 114/218 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1670C>A p.A557D | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- THADA | c.1899G>T p.Q633H | Missense Mutation (SNP) | VAF 144/343 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LCT | c.93C>T p.T31= | Silent (SNP) | VAF 35/362 reads (10%) | catalogued as rs777212413; called by muse, mutect2, varscan2
- OR4C5 | c.726C>A p.I242= | Silent (SNP) | VAF 202/472 reads (43%) | catalogued as rs1241885679; called by mutect2, varscan2
- ZBTB20 | c.855C>A p.P285= (on ENST00000474710 / NM_001164342.2; = p.P212= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 203/432 reads (47%) | called by muse, mutect2, varscan2
- KLK7 | chr19:50983927 C>A | 5'Flank (SNP) | VAF 53/157 reads (34%) | called by muse, mutect2, varscan2
- RUVBL1 | c.1212-45C>T | Intron (SNP) | VAF 44/104 reads (42%) | catalogued as rs368834831; called by muse, mutect2, varscan2
